Somatic mutation profile of tumor specimen MP2PRT-PASZMM-TMP1-A (aliquot MP2PRT-PASZMM-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASZMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,256 days).
Specimen MP2PRT-PASZMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceea7c3c-7b7d-4b87-adaa-242f410be75a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZMM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZMM-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3adf0c84-711a-4dc1-b75d-20564ee36db9

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 3, 3'Flank 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.7890G>C p.L2630F (on ENST00000359028; = p.L2606F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.831); catalogued as COSV100661927, COSV62360249; called by muse, mutect2, varscan2
- IGBP1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 219/575 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100643057; called by muse, mutect2, varscan2
- INSR | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57173643; called by muse, mutect2, varscan2
- IRS4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 280/651 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); catalogued as rs775726984, COSV64534044; called by muse, mutect2, varscan2
- LAMB4 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 22/480 reads (5%) | catalogued as COSV52713973; called by muse, mutect2
- RELN | c.6712G>A p.V2238I | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs749134304, COSV59025491; called by muse, mutect2, varscan2
- SETD2 | c.4501T>A p.C1501S | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57439746, COSV57444879; called by muse, mutect2, varscan2
- SULT1B1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 140/372 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100150358; called by muse, mutect2, varscan2
- YTHDC1 | c.866C>G p.S289* | Nonsense Mutation (SNP) | VAF 180/473 reads (38%) | catalogued as COSV60010485; called by muse, mutect2, varscan2
- AKAP9 | c.7612G>C p.E2538Q (on ENST00000359028; = p.E2514Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HS6ST2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 324/810 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PTPRD | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC17A4 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 192/429 reads (45%) | called by muse, mutect2, varscan2
- TRBJ2-7 | c.1delinsGG p.S2Vfs*? | Frame Shift Ins (INS) | VAF 159/429 reads (37%) | called by mutect2*, pindel, varscan2*
- COL7A1 | c.6006C>T p.R2002= | Silent (SNP) | VAF 258/614 reads (42%) | catalogued as rs200826090, COSV100097518; called by muse, mutect2, varscan2
- CRYBG3 | c.6981T>C p.V2327= | Silent (SNP) | VAF 85/229 reads (37%) | called by muse, mutect2, varscan2
- HTRA2 | c.1099C>T p.L367= | Silent (SNP) | VAF 147/320 reads (46%) | called by muse, mutect2, varscan2
- NRXN1 | c.4236C>T p.A1412= | Silent (SNP) | VAF 199/500 reads (40%) | catalogued as rs1238134606, COSV60520715; called by muse, mutect2, varscan2
- WDR11 | c.2883C>T p.N961= | Silent (SNP) | VAF 171/417 reads (41%) | called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714683 ins TTCTCCCAGGGACT | 3'Flank (INS) | VAF 36/86 reads (42%) | called by muse*, pindel
- IGHV3-11 | chr14:106116634 ins TGGGA | 3'Flank (INS) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- IGHV3-48 | chr14:106537809 ins TGGGA | 3'Flank (INS) | VAF 35/196 reads (18%) | called by pindel, varscan2
